Somatic mutation profile of tumor specimen MMRF_1499_1_BM_CD138pos (aliquot MMRF_1499_1_BM_CD138pos_T2_KAS5U_L02373) from MMRF case MMRF_1499, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.6 years (25,057 days).
Specimen MMRF_1499_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1715f865-7834-4308-9eee-3cd15684f6ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1499_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1499_2_PB_Whole_C7_KHS5U_L08085; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d913ede1-2e27-47e3-82f7-3c9556c6b62b

The open-access MAF lists 118 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 33, Silent 13, Intron 11, 3'Flank 5, 5'UTR 4, 5'Flank 3, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.401T>C p.F134S | Missense Mutation (SNP) | VAF 37/42 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM083195, COSV52669400, COSV52722353; called by muse, mutect2, varscan2
- BAHCC1 | c.7027G>A p.A2343T | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1463390495; called by muse, varscan2
- CKAP5 | c.2401C>T p.L801F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779812972, COSV100370787; called by muse, mutect2
- CYLD | c.2191C>T p.Q731* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV61097325; called by muse, mutect2, varscan2
- FBP2 | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64694223; called by muse, mutect2
- FLNC | c.4699C>T p.R1567W | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs369842920; ClinVar: uncertain significance; called by muse, mutect2
- FZD7 | c.1609A>G p.T537A | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as rs1342968635; called by muse, mutect2, varscan2
- GNPTAB | c.2198C>G p.S733* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV54779706; called by muse, mutect2, varscan2
- IGHD2-8 | c.5T>C p.I2T | Missense Mutation (SNP) | VAF 30/30 reads (100%) | catalogued as rs1419641314; called by mutect2, varscan2
- LRP1B | c.10747G>A p.D3583N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752198878, COSV67249373; called by muse, mutect2, varscan2
- MTMR7 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV51663172; called by muse, mutect2
- OR1N2 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs150868171, COSV65460456; called by muse, mutect2, varscan2
- PLEKHB1 | c.640A>C p.S214R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.946); catalogued as rs370479206; called by muse, mutect2, varscan2
- QARS1 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161729877, COSV60274795; called by muse, mutect2, varscan2
- SLC6A11 | c.1442T>C p.I481T | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as rs1309337363; called by muse, mutect2, varscan2
- UQCRC2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV51673316; called by muse, mutect2
- ZSCAN29 | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs773208736; called by muse, mutect2, varscan2
- ACTA1 | c.832_836del p.E278Hfs*9 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- ALG5 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 58/59 reads (98%) | SIFT tolerated (0.58); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- AZGP1 | c.889G>C p.A297P | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- BIRC6 | c.3908T>A p.I1303N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CEBPA | c.708C>A p.H236Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CEP57L1 | c.1254C>A p.N418K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTN5 | c.2026A>G p.I676V | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYLD | c.1735dup p.M579Nfs*36 | Frame Shift Ins (INS) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- DDX54 | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DTWD1 | c.398A>G p.K133R | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ELMOD3 | c.472A>C p.T158P | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- HEATR5A | c.5464+7G>A | Splice Region (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2
- IQCN | c.1004T>C p.I335T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LPAR2 | c.1-1G>A p.X1_splice | Splice Site (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- MOCS1 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MYO5C | c.4760C>T p.T1587M | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NFKB2 | c.1817T>C p.L606P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PAX5 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.395); called by muse, varscan2
- PCDHGA8 | c.1703C>A p.P568H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PDE4A | c.2192A>G p.Q731R (on ENST00000380702 / NM_001111307.2; = p.Q492R on NM_006202.3) | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RBM39 | c.1477G>T p.G493C (on ENST00000253363 / NM_001323424.2; = p.G487C on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REV1 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- RNF149 | c.314_316del p.G105del | In Frame Del (DEL) | VAF 16/19 reads (84%) | called by mutect2, varscan2
- SBF1 | c.3277A>C p.I1093L | Missense Mutation (SNP) | VAF 54/73 reads (74%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SETD5 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- TAS2R31 | c.505A>T p.R169W | Missense Mutation (SNP) | VAF 80/130 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); called by muse, varscan2
- TCHH | c.2961G>T p.E987D | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TEX47 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/300 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.173); called by muse, mutect2
- TOGARAM1 | c.2009G>T p.G670V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- TTC21A | c.2545A>G p.S849G | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- TYRP1 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 21/343 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- BTBD8 | c.3600G>A p.K1200= (on ENST00000636805 / NM_001376131.1; = p.K687= on NM_015237.4) | Silent (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- DHRS1 | c.867C>G p.G289= | Silent (SNP) | VAF 40/137 reads (29%) | called by muse, mutect2, varscan2
- ETNPPL | c.303G>A p.E101= | Silent (SNP) | VAF 68/151 reads (45%) | called by muse, mutect2, varscan2
- HAND1 | c.177C>T p.G59= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- KIF26A | c.4308G>A p.A1436= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs558868521; called by muse, mutect2, varscan2
- MYO1E | c.1401C>T p.C467= | Silent (SNP) | VAF 11/152 reads (7%) | catalogued as rs532227876, COSV55696301; called by muse, mutect2
- NR1D2 | c.330G>A p.A110= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as rs144648705; called by muse, mutect2, varscan2
- PKD2L2 | c.1506A>C p.S502= | Silent (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- PRC1 | c.226C>T p.L76= | Silent (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- WDR43 | c.594A>G p.K198= | Silent (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- ZMIZ1 | c.1647C>T p.S549= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs770912302; called by muse, mutect2, varscan2
- ZNF112 | c.2340G>A p.E780= (on ENST00000337401 / NM_001083335.2; = p.E774= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/209 reads (9%) | catalogued as rs1449518420; called by muse, mutect2
- ZNF619 | c.1569C>G p.P523= | Silent (SNP) | VAF 48/250 reads (19%) | catalogued as COSV59030410; called by muse, mutect2, varscan2
- AC011503.1 | n.467+8545T>C | Intron (SNP) | VAF 14/165 reads (8%) | catalogued as rs548991714; called by muse, mutect2
- AC103993.1 | n.631A>G | RNA (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- AEBP2 | c.*214T>C | 3'UTR (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- AMOTL1 | c.*3610C>A | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- ATP13A4 | chr3:193555030 C>T | 5'Flank (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2, varscan2
- ATPAF1 | chr1:46633422 ins T | 3'Flank (INS) | VAF 26/60 reads (43%) | called by mutect2, pindel, varscan2
- BCL9L | c.*3443G>T | 3'UTR (SNP) | VAF 18/261 reads (7%) | called by muse, mutect2
- CBL | c.*3423T>G | 3'UTR (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- CCDC73 | c.429+2205T>G | Intron (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- CD200R1L | c.*99G>T | 3'UTR (SNP) | VAF 14/347 reads (4%) | called by muse, mutect2
- CD274 | c.*856T>G | 3'UTR (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- CERS4 | c.*240del | 3'UTR (DEL) | VAF 19/43 reads (44%) | called by mutect2, pindel, varscan2
- CLASP2 | c.862+146G>A | Intron (SNP) | VAF 29/70 reads (41%) | catalogued as rs771455725; called by muse, mutect2, varscan2
- CREBZF | c.*287+62A>T | Intron (SNP) | VAF 195/414 reads (47%) | called by muse, varscan2
- CREBZF | c.*185T>A | 3'UTR (SNP) | VAF 163/356 reads (46%) | called by muse, varscan2
- CYP11A1 | c.*38C>A | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- DOK3 | chr5:177503191 del A | 3'Flank (DEL) | VAF 36/78 reads (46%) | called by mutect2, pindel, varscan2
- FOXM1 | chr12:2857638 C>T | 3'Flank (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- GATAD1 | c.*205A>G | 3'UTR (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- GHRHR | c.269-170C>T | Intron (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- GPR22 | c.*133C>G | 3'UTR (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- GTPBP1 | c.*463G>A | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- IGSF23 | c.-21C>T | 5'UTR (SNP) | VAF 57/272 reads (21%) | catalogued as rs765217807; called by muse, mutect2, varscan2
- JPH3 | chr16:87701646 C>T | 3'Flank (SNP) | VAF 72/77 reads (94%) | called by muse, mutect2, varscan2
- KCNAB1 | c.*371A>G | 3'UTR (SNP) | VAF 5/121 reads (4%) | catalogued as rs1187650077; called by muse, mutect2
- KCNE3 | c.*328G>A | 3'UTR (SNP) | VAF 75/180 reads (42%) | called by muse, mutect2, varscan2
- LIFR | c.*4345C>T | 3'UTR (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- LRATD1 | c.*100G>A | 3'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- LRATD1 | c.*1428G>A | 3'UTR (SNP) | VAF 46/48 reads (96%) | called by muse, mutect2, varscan2
- LRP1 | c.*347C>T | 3'UTR (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- MRPS25 | c.*123T>C | 3'UTR (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
- MTR | c.*3523G>A | 3'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- NCALD | c.*137G>A | 3'UTR (SNP) | VAF 16/194 reads (8%) | catalogued as rs552054540, COSV99636818; called by muse, mutect2
- NIBAN3 | c.-8G>T | 5'UTR (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- NXPH2 | c.-36G>A | 5'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2
- PAPOLB | c.*1603G>T | 3'UTR (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- PGF | chr14:74942488 G>A | 3'Flank (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PRAME | chr22:22559268 C>A | 5'Flank (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2
- RNASEH2B | c.436+147C>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs540876800; called by muse, mutect2, varscan2
- RNF180 | c.1227+370A>T | Intron (SNP) | VAF 14/22 reads (64%) | called by muse, varscan2
- RNF217 | c.*5200G>C | 3'UTR (SNP) | VAF 6/25 reads (24%) | catalogued as rs963645124; called by muse, mutect2, varscan2
- RPL13A | c.343-34C>T | Intron (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- RPL14 | c.3+55C>T | Intron (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2
- RRM2 | c.798+93G>A | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as rs1034904578; called by muse, mutect2, varscan2
- RTP1 | c.273-50C>A | Intron (SNP) | VAF 45/197 reads (23%) | catalogued as rs778254540; called by muse, mutect2, varscan2
- SBF2 | c.*1462T>C | 3'UTR (SNP) | VAF 28/166 reads (17%) | called by muse, mutect2, varscan2
- SH2B2 | chr7:102283317 A>C | 5'Flank (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*6380C>G | 3'UTR (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- SLC22A11 | c.*1225G>A | 3'UTR (SNP) | VAF 47/90 reads (52%) | catalogued as rs769418122; called by muse, mutect2, varscan2
- SMU1 | c.*2970T>G | 3'UTR (SNP) | VAF 64/144 reads (44%) | called by muse, mutect2, varscan2
- STAMBPL1 | c.*1784G>C | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- SYT9 | c.*1216A>G | 3'UTR (SNP) | VAF 11/129 reads (9%) | called by muse, mutect2
- TP63 | c.*2108G>T | 3'UTR (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- TSPAN9 | c.*2670G>A | 3'UTR (SNP) | VAF 27/31 reads (87%) | called by muse, mutect2, varscan2
- UBXN1 | c.-50C>G | 5'UTR (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- VGLL3 | c.*8163T>C | 3'UTR (SNP) | VAF 29/77 reads (38%) | catalogued as rs367691681; called by muse, mutect2, varscan2
- VPS41 | c.*3072C>T | 3'UTR (SNP) | VAF 32/77 reads (42%) | catalogued as rs1054614180; called by muse, mutect2, varscan2
